CCDI case PBBRBI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/e7e24b20-b48a-4151-b544-bf4de6cba3a9

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.0 years (6,219 days).

Biospecimens (3 samples)
- Sample 0DEP1H: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEP1Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DEP1R: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
